HCMI case HCM-BROD-0019-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5c2bff0f-0e8e-4d98-83c5-0d9ab866241a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1935; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Classification of tumor: primary; Age at diagnosis: 80.6 years (29,434 days); AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; Tumor grade: G1; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 0; Peripancreatic lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Gemcitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 58 days; Days to treatment end: 212 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 694, day 1,189.

Molecular and laboratory tests
- CA19-9: 8.
- CEA: 2; Blood test normal range upper: 2.5.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80.8 kg; Height: 164.2 cm; BMI: 30.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Days to comorbidity: -2,136 days (-5.8 years); Diabetes treatment type: Injected Insulin.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Alcohol intensity: Non-Drinker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0019-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-BROD-0019-C25-01B-01-S1-HE: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 26.
  Slide HCM-BROD-0019-C25-01B-01-S2-HE: Section location: Bottom; Percent tumor cells: 35; Percent tumor nuclei: 35; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 6; Percent neutrophil infiltration: 20.
- Sample HCM-BROD-0019-C25-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0019-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 20.
